Somatic mutation profile of tumor specimen TCGA-BP-4993-01A (aliquot TCGA-BP-4993-01A-02D-1421-08) from TCGA case TCGA-BP-4993, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 58.6 years (21,407 days).
Specimen TCGA-BP-4993-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 570a1ee4-f502-4949-a754-cc85f18c3201.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4993-11A (Solid Tissue Normal), aliquot TCGA-BP-4993-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c01fa05-cfac-4931-9ba2-a78258202661

The open-access MAF lists 70 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Frame Shift Del 7, Nonsense Mutation 4, Frame Shift Ins 1, Splice Site 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.3652A>G p.I1218V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV59197640; called by muse, mutect2, varscan2
- AGTPBP1 | c.2446G>A p.V816I (on ENST00000357081 / NM_001330701.2; = p.V776I on NM_015239.2) | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1472141503, COSV100430483, COSV61271505; called by muse, mutect2, varscan2
- AGXT | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM072846, COSV56753966; called by muse, mutect2, varscan2
- ARHGAP17 | c.2357C>A p.T786N (on ENST00000289968 / NM_001006634.3; = p.T708N on NM_018054.6) | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV51507098; called by muse, mutect2, varscan2
- ATP1A2 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs779812635, COSV63402362, COSV63403685; called by muse, mutect2
- CD4 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV50590613; called by muse, mutect2
- CHD9 | c.4945G>A p.V1649I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.07); catalogued as COSV54610258; called by muse, mutect2
- CNGB3 | c.2226A>T p.K742N | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV60689600; called by muse, mutect2
- CS | c.857A>T p.Y286F | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.619); catalogued as COSV57524645; called by muse, mutect2, varscan2
- DDX5 | c.1843T>C p.*615Qext*24 | Nonstop Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV56749035; called by muse, mutect2, varscan2
- DNAI3 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54002396; called by muse, mutect2, varscan2
- DUOXA1 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV50993544; called by muse, mutect2
- DUOXA1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1223359174, COSV50993554; called by muse, mutect2
- FIG4 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57787499; called by muse, mutect2
- GNB1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs780752397, COSV66100559; called by muse, mutect2, varscan2
- HEPHL1 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59891858; called by muse, mutect2, varscan2
- ITGA3 | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV50311084; called by muse, mutect2, varscan2
- LRFN3 | c.1649C>A p.S550* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV55817224, COSV55817686; called by muse, mutect2
- LUZP1 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV56501042; called by muse, mutect2, varscan2
- LYPD2 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV63649396, COSV63649517; called by muse, mutect2, varscan2
- MAGEC1 | c.635G>C p.S212T | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV53572574; called by muse, mutect2
- MAP7D3 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs769036348, COSV60170926; called by muse, mutect2, varscan2
- MCCC2 | c.823C>G p.H275D | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV60154392; called by muse, mutect2, varscan2
- MCM3AP | c.2464A>T p.R822* | Nonsense Mutation (SNP) | VAF 50/138 reads (36%) | catalogued as COSV52439562; called by muse, mutect2, varscan2
- MUC16 | c.11194T>A p.S3732T | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV67464933; called by muse, mutect2, varscan2
- NEGR1 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs776574702, COSV100747038, COSV63248672; called by muse, mutect2, varscan2
- NLRP7 | c.1307A>G p.E436G | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV60174330; called by muse, mutect2
- NOX4 | c.1322T>G p.I441R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54452972; called by muse, mutect2, varscan2
- NPPB | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV64687553; called by muse, mutect2, varscan2
- OPRD1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52381615; called by muse, mutect2, varscan2
- OPRM1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs199984546, COSV100001175, COSV57674063; called by muse, mutect2, varscan2
- PAK5 | c.2129T>A p.V710D | Missense Mutation (SNP) | VAF 112/347 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV62024307, COSV62027105; called by muse, mutect2, varscan2
- PANK2 | c.1579A>C p.N527H (on ENST00000316562 / NM_153638.3; = p.N236H on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.69); catalogued as COSV57254244; called by muse, mutect2
- PBRM1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as COSV56273176; called by muse, mutect2, varscan2
- PCDH10 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 37/144 reads (26%) | catalogued as COSV52089049, COSV52093666; called by muse, mutect2, varscan2
- PRPF3 | c.1085C>G p.T362R | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61394763; called by muse, mutect2, varscan2
- RANBP2 | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV51700962; called by muse, mutect2, varscan2
- RIOK3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV59773004; called by muse, mutect2
- RPAP1 | c.3356G>A p.G1119E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58538894; called by muse, mutect2, varscan2
- SFXN1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866735283, COSV58493326; called by muse, mutect2
- SMC2 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53958030; called by muse, mutect2, varscan2
- SMOX | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as rs1294645351, COSV53864802; called by muse, mutect2, varscan2
- SYK | c.717+1G>A p.X239_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | catalogued as COSV65327080; called by muse, mutect2, varscan2
- VHL | c.567del p.D190Tfs*12 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs121913345, COSV56542984; called by mutect2, pindel, varscan2
- ZNF112 | c.719T>C p.I240T (on ENST00000337401 / NM_001083335.2; = p.I234T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1292746852, COSV61619968; called by muse, mutect2, varscan2
- AGO4 | c.329del p.P110Qfs*19 | Frame Shift Del (DEL) | VAF 40/302 reads (13%) | called by mutect2, pindel, varscan2
- CCDC8 | c.1448del p.P483Lfs*39 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | called by mutect2, varscan2
- CLCN3 | c.1491_1494del p.Y497* | Frame Shift Del (DEL) | VAF 45/233 reads (19%) | called by mutect2, pindel, varscan2
- FKTN | c.833del p.K278Rfs*6 | Frame Shift Del (DEL) | VAF 34/179 reads (19%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- KLRC2 | c.451del p.S151Vfs*5 | Frame Shift Del (DEL) | VAF 83/433 reads (19%) | called by mutect2, pindel, varscan2
- MAML3 | c.2727del p.G910Efs*3 | Frame Shift Del (DEL) | VAF 92/353 reads (26%) | called by mutect2, pindel, varscan2
- TET3 | c.4349dup p.N1450Kfs*21 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- ACOT2 | c.81C>G p.V27= | Silent (SNP) | VAF 87/276 reads (32%) | catalogued as COSV53150331; called by muse, mutect2, varscan2
- CAMK1D | c.219G>T p.L73= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV66611267; called by muse, mutect2, varscan2
- CASKIN1 | c.1476C>T p.N492= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV58872490; called by muse, mutect2, varscan2
- CDC14A | c.1653A>T p.P551= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV60558322; called by muse, mutect2
- CTDNEP1 | c.606C>A p.I202= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV56641940; called by muse, mutect2
- DEFB116 | c.255C>T p.Y85= | Silent (SNP) | VAF 100/404 reads (25%) | catalogued as rs552225179, COSV68722084, COSV68722375; called by muse, mutect2, varscan2
- FXR2 | c.213A>G p.E71= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV51518634; called by muse, mutect2, varscan2
- GPR19 | c.111C>T p.S37= | Silent (SNP) | VAF 79/214 reads (37%) | catalogued as COSV60123468; called by muse, mutect2, varscan2
- MARCHF10 | c.2091G>T p.V697= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as COSV60886183, COSV60887100; called by muse, mutect2, varscan2
- MN1 | c.3738G>A p.A1246= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs767225766, COSV56558267; called by muse, mutect2, varscan2
- MROH6 | c.69A>G p.A23= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs200279480, COSV52784969; called by muse, mutect2
- NOXRED1 | c.285G>A p.L95= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1188362213, COSV53628013; called by muse, mutect2, varscan2
- SAMD9 | c.3522G>A p.E1174= | Silent (SNP) | VAF 33/430 reads (8%) | catalogued as COSV66075087; called by muse, mutect2
- SYNCRIP | c.1518T>C p.A506= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV100784086, COSV62287675; called by muse, mutect2, varscan2
- THAP11 | c.588T>C p.F196= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV54646012; called by muse, mutect2, varscan2
- ZNF532 | c.1947T>C p.C649= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs1313071165, COSV60173008; called by muse, mutect2
- KIR3DX1 | n.697G>A | RNA (SNP) | VAF 5/91 reads (5%) | catalogued as rs533690166, COSV99683188; called by muse, mutect2
